Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81M, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81M-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: right adrenal

Grossly, there is a red to brownish tumor with a diameter of 5.5 cm. Histologically, there is a tumor surrounded by a fibrous capsule. The tumor is composed with Zellballen, sometimes with trabecular architecture. Nuclei are round to oval with smooth chromatin. In septal areas around the zellballen numerous dilated blood vessels are visible. Single necrosis are found in the center. No significant increase in the number of mitoses, no profound nuclear pleomorphism, vessel invasion or capsule destruction.

Final diagnosis: pheochromocytoma

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/0
Site: (R) Adrenal gland NOS C74.9
JW 10/17/13

Source: NCI Genomic Data Commons file 13debf3b-ee2f-4548-b1ef-f252e648140e (TCGA-WB-A81M.CE4F162C-E64F-4BFC-93C0-B3ECB6B6D587.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).